Somatic mutation profile of tumor specimen TCGA-F5-6812-01A (aliquot TCGA-F5-6812-01A-11D-1826-10) from TCGA case TCGA-F5-6812, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.0 years (24,490 days).
Specimen TCGA-F5-6812-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f0177e1-b7c8-4d5e-862d-1676905c8f65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6812-10A (Blood Derived Normal), aliquot TCGA-F5-6812-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2b32e7a-4e06-4930-b8d0-34c0d179324b

The open-access MAF lists 90 somatic variants for this specimen: 73 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 16, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 1, Translation Start Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4012C>T p.Q1338* | Nonsense Mutation (SNP) | VAF 41/80 reads (51%) | hotspot (GDC flag); catalogued as rs121913327, CM930029, COSV57325971; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 30/123 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / drug response; called by muse, varscan2
- TP53 | c.815T>G p.V272G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660333, CM942122, COSV52701102, COSV52773741, COSV52787833, COSV53259929; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ACTRT1 | c.622A>T p.N208Y | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV64420202; called by muse, mutect2, varscan2
- AKAP6 | c.3835G>T p.A1279S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV99797862; called by muse, mutect2, varscan2
- ARMCX2 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs782086194, COSV100168087, COSV57531153; called by muse, mutect2, varscan2
- ATP5F1C | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs778288834, COSV59620901; called by muse, mutect2, varscan2
- ATP8B1 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as rs775370485, COSV52177909; called by muse, mutect2, varscan2
- C1RL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99864374; called by muse, mutect2, varscan2
- CABLES2 | c.1047G>T p.R349S | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV54157118, COSV54158959; called by muse, mutect2, varscan2
- CCDC124 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV101506478; called by muse, mutect2, varscan2
- CDS1 | c.851T>G p.F284C | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV55691486; called by muse, mutect2, varscan2
- CPA1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs537076438, COSV50576261; called by muse, mutect2, varscan2
- CRYBB1 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as rs767583919, COSV53232665; called by muse, mutect2, varscan2
- DEAF1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV58609882; called by muse, mutect2, varscan2
- DIP2B | c.3260C>T p.T1087M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778799678, COSV99997801; called by muse, mutect2, varscan2
- DLL1 | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV100815896; called by muse, mutect2, varscan2
- DNAH17 | c.6694C>T p.R2232W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756421317, COSV67753244; called by muse, mutect2, varscan2
- EMCN | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs199976013; called by muse, mutect2, varscan2
- ESCO2 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV59417002; called by muse, mutect2, varscan2
- FAM47A | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.361); catalogued as COSV60495353, COSV60496508; called by muse, mutect2, varscan2
- FAT3 | c.3832G>T p.A1278S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV53188186; called by muse, mutect2
- FAT3 | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV53139761; called by muse, mutect2
- FN1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs993058472, COSV60566369; called by muse, mutect2, varscan2
- GBF1 | c.4606C>T p.R1536C (on ENST00000369983 / NM_001377137.1; = p.R1535C on NM_004193.3) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs1449597287, COSV64149921; called by muse, mutect2, varscan2
- GREM2 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58956363; called by muse, mutect2, varscan2
- GRIA3 | c.2552G>A p.R851Q | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs1395100721, COSV52084196; called by muse, mutect2, varscan2
- GTF3C1 | c.4988A>T p.N1663I | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV100648898; called by muse, mutect2, varscan2
- HECTD3 | c.764A>C p.E255A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV55802342; called by muse, mutect2
- HIPK2 | c.1807A>G p.I603V | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61226262; called by muse, mutect2, varscan2
- IL1RL2 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51819998; called by muse, mutect2
- KEL | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs143217520, COSV62333081; called by muse, mutect2, varscan2
- KMO | c.1135C>G p.Q379E | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV59368009; called by muse, mutect2, varscan2
- LAMA5 | c.9003G>T p.L3001F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV99437708; called by muse, mutect2
- LGALS12 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748637575, COSV55369432; called by muse, mutect2, varscan2
- METTL25 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV50262948; called by muse, mutect2, varscan2
- MGAT4B | c.975C>A p.D325E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.548); catalogued as rs141460358; called by muse, mutect2, varscan2
- MLLT10 | c.2063G>T p.R688L (on ENST00000307729 / NM_001195626.3; = p.R704L on NM_004641.3) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56997380, COSV57001896; called by muse, mutect2, varscan2
- MUSK | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 16/27 reads (59%) | catalogued as rs764615519, COSV51892336; called by muse, mutect2, varscan2
- NRXN1 | c.896A>T p.N299I | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV58502209; called by muse, mutect2, varscan2
- PDS5A | c.3695G>A p.S1232N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV57824498; called by muse, mutect2, varscan2
- PLAA | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68305765; called by muse, mutect2, varscan2
- PLXND1 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs773387450, COSV60710098; called by muse, mutect2
- PPP1R17 | c.353A>G p.D118G | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100566262; called by muse, mutect2, varscan2
- PRAMEF12 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs375662448; called by muse, mutect2, varscan2
- PRKRA | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV57871016; called by muse, mutect2, varscan2
- PROM1 | c.1796A>G p.E599G | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV101477099, COSV71700171; called by muse, mutect2, varscan2
- PSG7 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); catalogued as COSV101343182; called by muse, mutect2
- PTPN13 | c.860T>A p.I287N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57419495; called by muse, mutect2, varscan2
- PTPRC | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.071); catalogued as COSV61421806; called by muse, mutect2, varscan2
- RBM11 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs767760971, COSV68747974; called by muse, mutect2, varscan2
- RELN | c.6303-1G>A p.X2101_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100632136; called by muse, mutect2
- RINT1 | c.393T>G p.I131M | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57561250; called by muse, mutect2, varscan2
- RPE65 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.232); catalogued as rs752990312, COSV52018917; called by muse, mutect2, varscan2
- RPL11 | c.383A>T p.D128V (on ENST00000374550 / NM_001199802.1; = p.D129V on NM_000975.5) | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV65779079; called by muse, mutect2, varscan2
- SCG2 | c.1387C>G p.L463V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.853); catalogued as COSV59542159; called by muse, mutect2, varscan2
- SH3BP4 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV60645587, COSV60647184; called by muse, mutect2, varscan2
- SLC26A7 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV52606675; called by muse, mutect2, varscan2
- SLITRK2 | c.706_712del p.V236Wfs*17 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as COSV59429697; called by mutect2, pindel, varscan2
- SOX5 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV58652306; called by muse, mutect2, varscan2
- SPHKAP | c.4386C>A p.D1462E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60898421; called by muse, mutect2, varscan2
- TRAF1 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs371039591; called by muse, mutect2, varscan2
- UBAP2 | c.2315G>A p.G772E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV62549444; called by muse, mutect2, varscan2
- WDR33 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779537208; called by muse, mutect2, varscan2
- XIRP2 | c.6818C>A p.T2273N (on ENST00000628543; = p.T2448N on NM_152381.6) | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764812889, COSV54741001; called by muse, mutect2, varscan2
- ZBTB49 | c.224T>C p.I75T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145711052; called by muse, mutect2, varscan2
- ZNF41 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV57445734; called by muse, mutect2, varscan2
- ZNF648 | c.1594T>C p.Y532H | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV60573127; called by muse, mutect2, varscan2
- ZNF669 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV100594213; called by muse, mutect2, varscan2
- ZNF804B | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV60822486, COSV60862548; called by muse, mutect2, varscan2
- PRAMEF20 | c.858G>C p.Q286H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REEP3 | c.272del p.F91Sfs*29 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- CDK14 | c.870C>T p.N290= (on ENST00000380050 / NM_001287135.2; = p.N272= on NM_012395.3) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1394156466, COSV56056034; called by muse, mutect2, varscan2
- CREB3L3 | c.1095C>T p.N365= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs754995668, COSV50222736; called by muse, mutect2, varscan2
- DNAH8 | c.6444C>T p.C2148= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs777410917, COSV59443914; called by muse, mutect2, varscan2
- FAM78A | c.847C>A p.R283= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99908646; called by muse, mutect2
- FYN | c.87C>A p.R29= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as COSV57622710; called by muse, mutect2, varscan2
- ICE1 | c.4620A>G p.T1540= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1367331875, COSV56834437; called by muse, mutect2, varscan2
- JAK2 | c.156A>T p.A52= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV67688336; called by muse, mutect2, varscan2
- KRT82 | c.507C>T p.F169= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1443392350, COSV99233346; called by muse, mutect2, varscan2
- NEDD4 | c.1401C>T p.S467= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV59067691; called by muse, mutect2, varscan2
- OR10A5 | c.636C>T p.C212= | Silent (SNP) | VAF 36/172 reads (21%) | catalogued as COSV55056060; called by muse, mutect2, varscan2
- RYR1 | c.5019C>T p.C1673= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs543026464, COSV62096209; ClinVar: uncertain significance; called by mutect2, varscan2
- SALL4 | c.120G>A p.A40= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs768952911, COSV53856978; called by muse, varscan2
- STK31 | c.1401C>G p.R467= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV63454012, COSV63460222; called by muse, mutect2, varscan2
- TLR7 | c.429G>A p.P143= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs1341054327, COSV66125842; called by muse, mutect2, varscan2
- TNS1 | c.1413G>A p.S471= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs758569137, COSV50787224; called by muse, mutect2, varscan2
- XIRP2 | c.1777A>C p.R593= (on ENST00000628543; = p.R768= on NM_152381.6) | Silent (SNP) | VAF 25/161 reads (16%) | catalogued as COSV54740991, COSV99737409; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1043G>A | Intron (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63750174; called by muse, mutect2, varscan2
